CCDI case PBCSAZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c434b7c4-3b6b-4018-99d2-093e1f2e664b

Demographics
Sex at birth: male.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,553 days).

Biospecimens (3 samples)
- Sample 0DXZEJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXZEO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXZF6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
